Somatic mutation profile of tumor specimen C3N-00194-01 (aliquot CPT0014150006) from CPTAC case C3N-00194, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 51.7 years (18,885 days).
Specimen C3N-00194-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a72691c1-d1f8-4db5-8807-a06068307d87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00194-31 (Blood Derived Normal), aliquot CPT0015040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c6ec6b-4b95-494e-a8eb-5b01450e2e83

The open-access MAF lists 83 somatic variants for this specimen: 63 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 13, Frame Shift Del 7, Nonsense Mutation 4, Intron 3, Splice Site 2, RNA 2, 3'UTR 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143985153, CM004284, COSV56546846, COSV56547129; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30BL | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.196); catalogued as rs1248387408; called by muse, mutect2, varscan2
- CAPN2 | c.1245C>A p.H415Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV54339140; called by muse, mutect2
- CNTN4 | c.2058C>A p.S686R | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61876299; called by muse, mutect2
- DTWD1 | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1349922146, COSV52071861, COSV52072012; called by muse, mutect2, varscan2
- DYSF | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs139258703, CM055157; called by muse, mutect2, varscan2
- ERBB2 | c.2827C>A p.Q943K | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54073307; called by muse, mutect2, varscan2
- FGB | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1231024274; called by muse, mutect2, varscan2
- FRYL | c.6433G>A p.A2145T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51949370; called by muse, mutect2, varscan2
- KIAA0319L | c.392T>A p.L131* | Nonsense Mutation (SNP) | VAF 41/174 reads (24%) | catalogued as rs766020293; called by muse, mutect2, varscan2
- NKX6-2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs1289643272; called by muse, mutect2
- NSD1 | c.6703C>T p.H2235Y | Missense Mutation (SNP) | VAF 239/581 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); catalogued as rs1289043115; called by muse, mutect2, varscan2
- PDE1C | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as rs762050534, COSV58520743; called by muse, mutect2, varscan2
- PFKL | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57394605; called by muse, mutect2, varscan2
- PRX | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99398219; called by muse, mutect2, varscan2
- SI | c.4062+1G>T p.X1354_splice | Splice Site (SNP) | VAF 32/158 reads (20%) | catalogued as COSV100017400; called by muse, mutect2, varscan2
- SLC17A9 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374675240; called by muse, mutect2, varscan2
- ZNF292 | c.1598G>T p.R533L | Missense Mutation (SNP) | VAF 17/360 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100369839; called by muse, mutect2
- ZNF846 | c.143-7C>T | Splice Region (SNP) | VAF 8/118 reads (7%) | catalogued as rs776132841; called by muse, mutect2
- AC068580.4 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRD1 | c.1878G>C p.E626D | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- AKAP11 | c.3277G>C p.D1093H | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.3); called by muse, mutect2
- AMDHD2 | c.195del p.G66Dfs*62 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- ATP9A | c.874A>C p.K292Q | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C17orf100 | c.327del p.A110Pfs*56 | Frame Shift Del (DEL) | VAF 55/219 reads (25%) | called by mutect2, pindel, varscan2
- CCDC175 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CCT6B | c.1340T>G p.I447S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, varscan2
- CDH23 | c.4400T>A p.F1467Y | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DEFB134 | c.59-9_59-1del p.X20_splice | Splice Site (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel
- DEPDC1B | c.1413G>C p.K471N | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DNMT3L | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEFSEC | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.048); called by muse, mutect2
- EMILIN1 | c.1202C>T p.T401I | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- FAM120C | c.816C>G p.Y272* | Nonsense Mutation (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- FSCN1 | c.1216G>C p.A406P | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- GLYATL3 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- HS3ST4 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- MED30 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIDEAS | c.856del p.Q286Rfs*32 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel
- MTMR4 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- NINL | c.2200del p.R734Gfs*8 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel
- NKPD1 | c.1024del p.L342Wfs*64 | Frame Shift Del (DEL) | VAF 30/162 reads (19%) | called by mutect2, pindel, varscan2
- NPR1 | c.1309T>A p.S437T | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- OR52A1 | c.415A>T p.T139S | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2
- PCDH15 | c.5574del p.K1859Sfs*4 | Frame Shift Del (DEL) | VAF 116/508 reads (23%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.1498A>G p.M500V | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); called by muse, mutect2
- PNPLA1 | c.658T>C p.F220L (on ENST00000394571 / NM_001374623.1; = p.F125L on NM_173676.2) | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PNPLA5 | c.878A>C p.N293T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2
- PROM1 | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RANBP10 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SGPP1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC5A3 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPC24 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SPHK2 | c.348C>G p.C116W | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- STK32C | c.1249T>C p.S417P | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.885); called by muse, varscan2
- SUPV3L1 | c.2177C>G p.P726R | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SWSAP1 | c.493del p.Q165Sfs*33 (on ENST00000312423; = p.Q186Sfs*33 on NM_175871.4) | Frame Shift Del (DEL) | VAF 64/432 reads (15%) | called by mutect2, pindel*, varscan2
- TSC22D1 | c.3074A>C p.N1025T (on ENST00000458659 / NM_183422.4; = p.N96T on NM_006022.4) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TSGA10IP | c.1439C>A p.T480N | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2
- YLPM1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3221C>T p.T1074I | Missense Mutation (SNP) | VAF 40/377 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- ZNF469 | c.10352T>G p.M3451R (on ENST00000437464; = p.M3479R on NM_001367624.2) | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- DNAH17 | c.4969C>T p.L1657= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV67759268; called by muse, mutect2
- DPY19L1 | c.1797A>G p.E599= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- FAM181A | c.456C>T p.G152= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs777470544, COSV50889254, COSV50891030; called by muse, mutect2, varscan2
- GANAB | c.1326C>T p.D442= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2
- HS3ST4 | c.198G>A p.Q66= | Silent (SNP) | VAF 38/148 reads (26%) | called by muse, mutect2, varscan2
- LRRC49 | c.1458A>G p.A486= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as rs956094812; called by muse, mutect2, varscan2
- NR2F1 | c.759C>T p.R253= | Silent (SNP) | VAF 25/390 reads (6%) | catalogued as COSV59070007; called by muse, mutect2
- OR10J3 | c.615C>A p.V205= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as COSV59955736; called by muse, mutect2, varscan2
- PCDHGA5 | c.1905A>G p.R635= | Silent (SNP) | VAF 21/463 reads (5%) | called by muse, mutect2
- RUNDC1 | c.36G>A p.T12= | Silent (SNP) | VAF 73/349 reads (21%) | called by muse, mutect2, varscan2
- TGOLN2 | c.198C>T p.S66= | Silent (SNP) | VAF 17/384 reads (4%) | called by muse, mutect2
- TTN | c.10581T>A p.I3527= (on ENST00000591111; = p.I3481= on NM_003319.4) | Silent (SNP) | VAF 63/364 reads (17%) | called by muse, mutect2, varscan2
- VPS39 | c.2124T>A p.I708= (on ENST00000348544 / NM_001301138.2; = p.I697= on NM_015289.5) | Silent (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3228A>C | RNA (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- AP4B1 | c.*16del | 3'UTR (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- BBS4 | c.24+101G>T | Intron (SNP) | VAF 34/609 reads (6%) | called by muse, mutect2
- CABP7 | c.-50_-49del | 5'UTR (DEL) | VAF 21/117 reads (18%) | called by mutect2, pindel
- LINC01948 | n.390G>A | RNA (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- PRSS27 | c.237-41C>T | Intron (SNP) | VAF 33/196 reads (17%) | catalogued as rs200616593; called by muse, mutect2, varscan2
- SLC2A11 | c.984+192C>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
